Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7382, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7382-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONGUE, RIGHT PARTIAL GLOSSECTOMY: INVASIVE, MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.1 CM IN GREATEST DIMENSION; SURGICAL MARGINS NEGATIVE FOR MALIGNANCY (SEE COMMENT).

2) TONGUE, RIGHT PARTIAL GLOSSECTOMY: SKELETAL MUSCLE, NEGATIVE FOR MALIGNANCY

3) LYMPH NODES, RIGHT EXTERNAL JUGULAR, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY.

4) LYMPH NODES, LEFT LEVELS 1-4, EXCISION: 5 OF 42 LYMPH NODES INVOLVED BY METASTATIC SQUAMOUS CELL CARCINOMA.

5) LYMPH NODES, RIGHT LEVEL 1, EXCISION: 1 OF 6 LYMPH NODES INVOLVED BY METASTATIC SQUAMOUS CELL CARCINOMA.

6) LYMPH NODES, RIGHT LEVELS 2-4, EXCISION: 2 OF 34 LYMPH NODES INVOLVED BY METASTATIC SQUAMOUS CELL CARCINOMA.

COMMENT: The largest metastasis is 2.8 cm and there is no extranodal extension. This tumor corresponds to AJCC stage IVA (pT2pN2pM n/a).

**Electronically Signed Out by [REDACTED] **

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) partial glossectomy (frozen); 2) deep margin (frozen)3) R external jugular;
4)left level 1,2,3,4; 5)R level 1; 6)R level 2,3,4

GROSS DESCRIPTION:

1) SOURCE: Partial Glossectomy

[page 2 of 3]
Received fresh labeled "partial glossectomy" is a piece of tongue that measures 5.5 cm anterior to posterior, 3.5 cm medial to lateral, 1.7 cm superficial to deep. It contains an ulcerated mass that is firm and white and measures 3.1 x 2.8 cm. It is located in the center of the specimen. The surgeon indicated that this mass came from the right half of the tongue. The margins are inked in the following manner: deep-black, anterior-orange, posterior-green, medial-yellow, and lateral-blue. A small piece of tissue was set aside for research. All the margins are evaluated by frozen section review. The mass is then bread-loafed and it is homogenous and white-tan. Representative sections of the mass are submitted from lateral to medial. Summary of sections: 1AFSC-1BFSC, margin, 1AFSC, 3/1; 1BFSC, 2/1; 1C-1M, serial sections of entire specimen bisected including mass, 1C, 2/1; 1D-1H, 1/1; 1I, 2/1; 1J-1M, 1/1.

2) SOURCE: Deep Margin

Received fresh labeled "deep margin" is a 1.0 x 0.3 x 0.2 cm piece of unoriented pink soft tissue. It is submitted entirely for frozen section review.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Right External Jugular Node

Received fresh labeled "right external jugular node" is a packet of adipose tissue with a firm gray lymph node contained within it. The node measures 0.5 x 0.3 x 0.2 cm. It is submitted in its entirety.

Summary of sections: 3A, right external jugular node, 1/1.

4) SOURCE: Left Level 1,2,3,4

Received fresh labeled "left level 1, 2, 3, 4" is a packet of adipose tissue, lymph nodes, and a salivary gland. It measures 20.8 x 4.3 x 1.0 cm. This adipose packet is completely inspected and many lymph node candidates are identified. Some are large enough to be bisected and the largest measures 1.8 cm in greatest dimension. There is a large salivary gland that measures 4.0 cm in greatest dimension. Lymph node candidates are submitted as is a sample of the salivary gland.

Summary of sections: 4A-4E, bisected lymph node candidates, 4A-4D, 2/1, 4E, 1/1; 4F, representative sections of salivary gland, 2/1; 4G, lymph node candidates, 3/1; 4H, lymph node candidates, 4/1; 4I, lymph node candidates, 8/1; 4J, lymph node candidates, 8/1; 4K, lymph node candidates, 6/1; 4L, lymph node candidates, 8/1; 4M, lymph node candidates, 4/1; 4N, lymph node candidates, 5/1; 4O, lymph node candidates, 4/1; 4P, lymph node candidates, 5/1.

5) SOURCE: Right Level 1

Received fresh labeled "right neck level 1" is a packet of muscle, gland and adipose tissue measuring 7.8 x 5.8 x 1.9 cm. The specimen is inspected completely and lymph node candidates are submitted. There are several small candidates that measure 1.5 cm in greatest dimension. There is one large lymph node with a necrotic center that measures 2.8 cm in greatest dimension.

[page 3 of 3]
Summary of sections: 5A, 5B, representative sections of necrotic lymph node, 5A, 1/1, 5B, 2/1; 5C, lymph node candidate bisected, 2/1; 5D, 5E, representative sections of gland, 1/1 each; 5F-5H, lymph node candidates, 2/1 each.

6) SOURCE: Right Neck Level 2,3,4

Received fresh labeled "right neck level 2,3,4" is a packet of adipose tissue, muscle and lymph nodes measuring 6.2 x 1.2 cm. It is inspected completely and lymph node candidates are submitted. There are two large node candidates identified. The first measures 2.9 cm in greatest dimension. The other measures 2.4 cm. They are opened and have a brown interior with bits of calcification.

Summary of sections: 6A, 6B, necrotic lymph node candidate, 1/1 each; 6C, bisected lymph node candidate, 2/1; 6D, lymph node candidate, 2/1; 6E, lymph node candidate, 2/1; 6F, lymph node candidate, 4/1; 6G, lymph node candidate, 4/1; 6H, lymph node candidate, 2/1; 6I, lymph node candidate, 4/1; 6J, lymph node candidate, 3/1; 6K, lymph node candidate, 4/1.

[REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Partial Glossectomy

FROZEN SECTION DIAGNOSIS: ALL MARGINS NEGATIVE FOR CARCINOMA. [REDACTED]

2) SOURCE: Deep Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

Electronically signed by: [REDACTED] Attending Pathologist

Source: NCI Genomic Data Commons file 03bc2090-42a6-43a6-8e4c-a7a372fdf4f0 (TCGA-CR-7382.2909E68D-2518-40DB-9288-F21C1D44A779.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).